Somatic mutation profile of tumor specimen TCGA-L5-A8NF-01A (aliquot TCGA-L5-A8NF-01A-11D-A37C-09) from TCGA case TCGA-L5-A8NF, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 57.9 years (21,134 days).
Specimen TCGA-L5-A8NF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52aa29c3-d04a-42e6-9638-f180b3bc8d3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NF-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NF-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2cec82c-57f5-4990-99a3-1c64aad86dfe

The open-access MAF lists 134 somatic variants for this specimen: 99 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 32, Nonsense Mutation 12, Frame Shift Del 3, Frame Shift Ins 2, RNA 2, Splice Site 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL3 | c.2699G>T p.W900L (on ENST00000506720 / NM_001322402.2; = p.W832L on NM_015236.6) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV72230670; called by muse, mutect2
- ALOX5 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs143257667; called by muse, mutect2, varscan2
- ASPHD2 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.277); catalogued as rs140657637; called by muse, mutect2, varscan2
- ATP8A1 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 28/111 reads (25%) | catalogued as rs755553887, COSV100046625; called by muse, mutect2, varscan2
- BRCA2 | c.3775A>C p.S1259R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as rs587782071; ClinVar: uncertain significance; called by muse, varscan2
- BRINP3 | c.733del p.V245Yfs*16 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as COSV100819415; called by mutect2, pindel, varscan2
- CDH26 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54843744; called by muse, mutect2, varscan2
- COL14A1 | c.3761G>C p.G1254A | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1366139541; called by muse, mutect2
- CRYGB | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs755142633; called by muse, mutect2, varscan2
- CYP4F2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs1388353329, COSV55620300; called by muse, mutect2, varscan2
- DCP2 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as rs776321450, COSV66617267; called by muse, mutect2, varscan2
- DTNA | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV51996866; called by muse, mutect2, varscan2
- FGGY | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1348366009; called by muse, mutect2, varscan2
- FOXG1 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV57399660; called by muse, mutect2, varscan2
- GTPBP1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53285587, COSV99323524; called by muse, mutect2, varscan2
- HLA-C | c.295C>G p.R99G | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.939); catalogued as rs41549514, CM1412136; called by muse, mutect2, varscan2
- IGSF10 | c.3446C>T p.S1149F | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs997881807; called by muse, mutect2, varscan2
- INSR | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs747464322, COSV57165586; called by mutect2, varscan2
- LRRK2 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100111459; called by muse, mutect2, varscan2
- MYH13 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0.014); catalogued as COSV99353571, COSV99354319; called by muse, mutect2, varscan2
- MYO3A | c.3630A>C p.E1210D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV56337265, COSV56346975; called by mutect2, varscan2
- NEGR1 | c.1002C>A p.Y334* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as rs759861079, COSV60867943, COSV60874339; called by muse, mutect2, varscan2
- NID1 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs761421703, COSV51628836, COSV99937633; called by muse, mutect2, varscan2
- NUP210L | c.2490C>A p.F830L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV55141698; called by muse, mutect2, varscan2
- PCMTD1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764485169, COSV62119086; called by muse, mutect2
- PEX11B | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as rs782188850, COSV65197218; ClinVar: uncertain significance; called by muse, mutect2
- PKD1 | c.10588C>T p.Q3530* (on ENST00000262304 / NM_001009944.3; = p.Q3529* on NM_000296.4) | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as CM090561; called by muse, mutect2, varscan2
- PTPN21 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs918319665; called by muse, mutect2
- RBMXL2 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 21/46 reads (46%) | catalogued as COSV60978512; called by muse, mutect2, varscan2
- RPS6KL1 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV63580747; called by muse, mutect2, varscan2
- SAGE1 | c.326C>G p.A109G | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV61012185; called by muse, mutect2, varscan2
- SLC45A1 | c.1582G>A p.V528I | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs367968730; called by muse, mutect2, varscan2
- SYNGAP1 | c.3194C>T p.P1065L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as rs1014180310; ClinVar: likely benign; called by muse, mutect2, varscan2
- TPTE2 | c.357dup p.L120Sfs*19 (on ENST00000400230 / NM_199254.2; = p.L83Sfs*39 on NM_130785.3) | Frame Shift Ins (INS) | VAF 31/225 reads (14%) | catalogued as rs779618909; called by mutect2, pindel, varscan2
- TSHZ3 | c.1132T>C p.F378L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV53675742; called by muse, mutect2, varscan2
- TXNDC11 | c.534_538del p.F178Lfs*27 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | catalogued as rs762611107; called by mutect2, pindel, varscan2
- UBE3B | c.3040G>A p.V1014I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs376853832; called by muse, mutect2, varscan2
- USP26 | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs746595594; called by muse, mutect2, varscan2
- ZFC3H1 | c.384T>A p.S128R | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100350322; called by muse, mutect2, varscan2
- ZNF175 | c.467T>C p.M156T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1483058399; called by muse, mutect2, varscan2
- AICDA | c.30G>T p.K10N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by mutect2, varscan2
- ANKRD30A | c.239C>A p.A80D (on ENST00000611781; = p.A24D on NM_052997.2) | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- APOH | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ARSJ | c.1674A>C p.E558D | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASXL3 | c.5258T>C p.L1753S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BTAF1 | c.1738C>A p.L580M | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- CADPS | c.1322C>A p.P441Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CAVIN4 | c.869G>A p.R290K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CEMIP | c.1688G>A p.G563D | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CGB2 | c.471C>G p.D157E | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- CHRM2 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CNNM2 | c.2047G>A p.V683I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- COL13A1 | c.1938C>A p.G646= (on ENST00000398978 / NM_001130103.2; = p.G574= on NM_080798.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- CPZ | c.1702C>G p.P568A (on ENST00000360986 / NM_001014447.3; = p.P557A on NM_003652.3) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); called by mutect2, varscan2
- DBX1 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DOCK10 | c.5232G>C p.K1744N | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2
- DYNC1LI1 | c.811A>G p.I271V | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ERICH6 | c.1165A>G p.K389E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.295); called by muse, mutect2
- ERVW-1 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.217); called by muse, mutect2
- FBXO7 | c.1133G>C p.R378P | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTRA1 | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JAKMIP3 | c.444G>T p.E148D | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KRTAP1-5 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- LDHB | c.616_619del p.N206Wfs*9 | Frame Shift Del (DEL) | VAF 16/140 reads (11%) | called by mutect2, varscan2
- LINGO2 | c.625A>G p.K209E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MARVELD2 | c.683C>A p.S228* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- MRGPRX2 | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.6); called by muse, varscan2
- MTHFR | c.1596C>G p.Y532* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- MUC16 | c.24373A>C p.K8125Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- MXRA5 | c.5618T>C p.F1873S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- MYLK3 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by mutect2, varscan2
- NBEA | c.1343A>C p.N448T | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NBPF9 | c.1415A>C p.E472A | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- NCAM2 | c.959T>A p.L320H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEU4 | c.1232T>C p.V411A (on ENST00000391969 / NM_001167602.3; = p.V423A on NM_080741.4) | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- NUMA1 | c.5660C>T p.S1887F | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PADI1 | c.1018C>G p.P340A | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- PCNX2 | c.829_833dup p.S278Rfs*8 | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- PDE10A | c.1730A>C p.K577T | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PF4V1 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- PLCH2 | c.1385T>C p.L462P | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXDC1 | c.1160T>A p.L387H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- POLQ | c.7067C>T p.A2356V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- PPFIA1 | c.719A>C p.D240A | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2
- PPP1R3A | c.1066T>G p.L356V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- PRKG2 | c.178A>T p.K60* | Nonsense Mutation (SNP) | VAF 10/15 reads (67%) | called by muse, mutect2, varscan2
- PRLHR | c.657G>T p.E219D | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PSME1 | c.529T>C p.Y177H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM17 | c.1032_1050del p.X344_splice | Splice Site (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- RUNDC3B | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLITRK1 | c.75A>C p.K25N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- SNRNP200 | c.5608C>A p.Q1870K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- SORCS3 | c.1363C>G p.Q455E | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TEX13A | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- TRPC4 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- UBA1 | c.1876G>T p.E626* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- UBQLN3 | c.527T>C p.F176S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- VPS9D1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- XIRP2 | c.4894G>T p.D1632Y (on ENST00000628543; = p.D1807Y on NM_152381.6) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- AHI1 | c.786A>G p.E262= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- ANK1 | c.1968G>A p.S656= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs201462433, COSV55873671; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARAP1 | c.75G>T p.G25= | Silent (SNP) | VAF 49/368 reads (13%) | called by muse, mutect2, varscan2
- BMPER | c.1278C>T p.G426= | Silent (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- CCDC42 | c.570G>A p.Q190= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- CELA3A | c.426C>G p.A142= | Silent (SNP) | VAF 8/60 reads (13%) | called by mutect2, varscan2
- CELSR1 | c.3294G>A p.P1098= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs555754270, COSV99418184; called by muse, mutect2, varscan2
- COL5A3 | c.4740G>A p.A1580= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs781254667, COSV99319003; called by muse, mutect2, varscan2
- CRYBG3 | c.7755G>A p.K2585= | Silent (SNP) | VAF 29/51 reads (57%) | called by muse, mutect2, varscan2
- CSMD1 | c.7668C>T p.V2556= (on ENST00000520002; = p.V2555= on NM_033225.6) | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1355314705; called by muse, mutect2, varscan2
- DOCK3 | c.3165C>T p.T1055= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs964692983; called by muse, mutect2, varscan2
- FBN2 | c.3420C>T p.C1140= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs756541654, COSV52490627; ClinVar: likely benign; called by muse, mutect2, varscan2
- FRYL | c.1560A>G p.R520= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- GBP7 | c.492G>A p.E164= | Silent (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- ITGAX | c.2853C>A p.A951= | Silent (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- KCNC3 | c.1752G>A p.P584= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1001882554; ClinVar: benign; called by muse, mutect2, varscan2
- KRT27 | c.1377C>T p.S459= | Silent (SNP) | VAF 26/41 reads (63%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.3882C>T p.F1294= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs764474718; called by muse, mutect2, varscan2
- MMP16 | c.6C>T p.I2= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV54165771, COSV99689934; called by mutect2, varscan2
- MUC16 | c.33133C>T p.L11045= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs889386890, COSV101201997, COSV67490431; called by muse, mutect2, varscan2
- NEB | c.18729C>T p.S6243= | Silent (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- NPAS4 | c.1275T>G p.P425= | Silent (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2
- OR8B2 | c.690C>A p.S230= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV66665423; called by muse, mutect2, varscan2
- PCDHGB6 | c.978T>A p.G326= | Silent (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- PCNT | c.4662T>C p.D1554= | Silent (SNP) | VAF 26/30 reads (87%) | called by muse, mutect2, varscan2
- PDE6A | c.258C>T p.C86= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs908465502; called by muse, mutect2
- SCN1A | c.5511G>A p.P1837= (on ENST00000303395 / NM_001202435.3; = p.P1826= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/47 reads (57%) | called by muse, mutect2, varscan2
- SEMA3G | c.960G>A p.G320= | Silent (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- SLC10A5 | c.777G>A p.R259= | Silent (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- SLC46A2 | c.240C>A p.I80= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- TARDBP | c.678C>T p.F226= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99534510; called by muse, mutect2, varscan2
- UGT2B28 | c.1263G>C p.S421= | Silent (SNP) | VAF 31/123 reads (25%) | called by muse, mutect2, varscan2
- AP2A2 | c.*936_*942del | 3'UTR (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- LINC02145 | n.203G>C | RNA (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- SSPOP | n.3730dup | RNA (INS) | VAF 17/42 reads (40%) | catalogued as rs754581521; called by mutect2, pindel, varscan2
